Somatic mutation profile of tumor specimen MP2PRT-PAUFIS-TMP1-A (aliquot MP2PRT-PAUFIS-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUFIS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,465 days).
Specimen MP2PRT-PAUFIS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4767eb30-a7e4-4cfe-95be-a891c2eb6820.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFIS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFIS-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8df13ba6-ebca-4859-b715-f49e4f52b343

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Nonsense Mutation 4, Intron 2, In Frame Ins 1, Frame Shift Del 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- METTL14 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 61/290 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- MYO15A | c.3505C>T p.R1169* | Nonsense Mutation (SNP) | VAF 120/407 reads (29%) | catalogued as rs781546107; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 97/357 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV53893047; called by muse, mutect2, varscan2
- ARL2 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 152/452 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55861012; called by muse, mutect2, varscan2
- CABLES1 | c.1861G>A p.E621K (on ENST00000256925 / NM_001100619.2; = p.E356K on NM_138375.2) | Missense Mutation (SNP) | VAF 114/393 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs746942462, COSV56936213; called by muse, mutect2, varscan2
- CD300E | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 29/443 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs868319145; called by muse, mutect2
- FAM47C | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 246/270 reads (91%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as rs782236901, COSV100792871; called by muse, mutect2, varscan2
- FMO2 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV52947614; called by muse, mutect2, varscan2
- KMT2A | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV63284552, COSV63286241; called by muse, mutect2, varscan2
- LRP1 | c.5125G>A p.V1709I | Missense Mutation (SNP) | VAF 115/354 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs777149357, COSV54504405, COSV54514678; called by muse, mutect2, varscan2
- LTK | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); catalogued as rs145538913; called by muse, varscan2
- PHACTR4 | c.1960C>G p.Q654E (on ENST00000373839 / NM_001350159.2; = p.Q664E on NM_023923.4) | Missense Mutation (SNP) | VAF 138/436 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV65784471; called by muse, mutect2, varscan2
- RGPD4 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 142/506 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV61745016; called by muse, mutect2, varscan2
- RHBDF1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 297/713 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1477712060; called by muse, mutect2, varscan2
- SMARCA5 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 249/836 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs769379037; called by muse, mutect2, varscan2
- TMEM239 | c.284C>T p.S95L (on ENST00000361033 / NM_001318207.1; = p.S52L on NM_001167670.3) | Missense Mutation (SNP) | VAF 180/614 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs757335069; called by muse, mutect2, varscan2
- ZMIZ1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 322/689 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs200441362; called by muse, mutect2, varscan2
- AC011005.1 | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 192/632 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AC242842.3 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 126/631 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- AFTPH | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- AMOTL2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 175/758 reads (23%) | called by muse, mutect2, varscan2
- ANKRD31 | c.3718C>G p.L1240V | Missense Mutation (SNP) | VAF 5/147 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ARHGAP12 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- CAMSAP1 | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 14/488 reads (3%) | called by muse, mutect2
- CNTNAP4 | c.1766T>C p.I589T | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAH5 | c.12774C>G p.D4258E | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- FAT3 | c.5977G>A p.E1993K | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FIGN | c.1709C>G p.S570C | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- GCKR | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2
- GPR182 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 132/455 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- HRNR | c.6037T>C p.S2013P | Missense Mutation (SNP) | VAF 204/1818 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, varscan2
- KRTAP10-11 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LRBA | c.865_872delinsCCC p.C289Pfs*3 | Frame Shift Del (DEL) | VAF 46/161 reads (29%) | called by pindel, varscan2*
- MFHAS1 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 106/362 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NAALADL2 | c.1080_1081insTCC p.Y360_P361insS | In Frame Ins (INS) | VAF 156/781 reads (20%) | called by mutect2, pindel, varscan2
- NEK10 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OSM | c.646C>G p.P216A | Missense Mutation (SNP) | VAF 46/740 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.067); called by muse, mutect2
- PANX3 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH19 | c.2681C>G p.S894C (on ENST00000373034 / NM_001184880.2; = p.S846C on NM_020766.3) | Missense Mutation (SNP) | VAF 117/170 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PIH1D1 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 91/342 reads (27%) | called by muse, mutect2, varscan2
- PKD1L3 | c.4290C>A p.S1430R | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RAPGEF5 | c.991A>G p.N331D (on ENST00000401957 / NM_001367602.2; = p.N634D on NM_012294.5) | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RPS5 | c.151C>G p.H51D | Missense Mutation (SNP) | VAF 118/313 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC16B | c.2503G>A p.G835R | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); called by muse, mutect2
- SIGLEC10 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 35/534 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2
- TTN | c.21161C>A p.T7054N (on ENST00000591111; = p.T6127N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/383 reads (40%) | PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF804B | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- EIF2AK4 | c.4401C>T p.F1467= | Silent (SNP) | VAF 81/226 reads (36%) | catalogued as rs200983505, COSV55468086; called by muse, mutect2, varscan2
- FBN3 | c.2916C>T p.F972= | Silent (SNP) | VAF 128/401 reads (32%) | catalogued as rs776718524; called by muse, mutect2, varscan2
- INPPL1 | c.837G>A p.Q279= | Silent (SNP) | VAF 51/195 reads (26%) | called by muse, mutect2, varscan2
- ITGA3 | c.1143G>A p.Q381= | Silent (SNP) | VAF 70/293 reads (24%) | called by muse, mutect2, varscan2
- NLGN2 | c.1224C>T p.F408= | Silent (SNP) | VAF 96/336 reads (29%) | called by muse, varscan2
- OPTC | c.945C>G p.L315= | Silent (SNP) | VAF 162/569 reads (28%) | catalogued as COSV65868126; called by muse, mutect2, varscan2
- PDHA2 | c.552C>T p.N184= | Silent (SNP) | VAF 255/521 reads (49%) | catalogued as rs1448922583, COSV54779922; called by muse, mutect2, varscan2
- PNPLA7 | c.1722G>A p.A574= | Silent (SNP) | VAF 235/537 reads (44%) | catalogued as rs527520264, COSV99480568; called by muse, mutect2, varscan2
- SEMA4G | c.2067C>T p.L689= (on ENST00000370250; = p.L694= on NM_017893.3) | Silent (SNP) | VAF 147/449 reads (33%) | catalogued as rs779930213; called by muse, mutect2, varscan2
- SERPINA12 | c.873T>A p.T291= | Silent (SNP) | VAF 99/315 reads (31%) | called by muse, mutect2, varscan2
- SORCS3 | c.2616C>T p.F872= | Silent (SNP) | VAF 122/453 reads (27%) | catalogued as rs868718609; called by muse, mutect2, varscan2
- SYNDIG1L | c.198C>T p.A66= | Silent (SNP) | VAF 215/510 reads (42%) | called by muse, mutect2, varscan2
- TENM2 | c.7869G>A p.K2623= (on ENST00000518659 / NM_001122679.2; = p.K2384= on NM_001080428.3) | Silent (SNP) | VAF 50/560 reads (9%) | catalogued as rs1453228926; called by muse, mutect2
- DDHD1 | chr14:53153009 C>T | 5'Flank (SNP) | VAF 267/779 reads (34%) | catalogued as rs1426121525; called by muse, mutect2, varscan2
- DOCK9 | c.3697+16C>T | Intron (SNP) | VAF 106/410 reads (26%) | catalogued as rs913529236; called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031472 ins AGGG | 3'Flank (INS) | VAF 78/169 reads (46%) | called by mutect2, pindel, varscan2
- KIF1B | c.2115+7060C>G | Intron (SNP) | VAF 134/451 reads (30%) | called by muse, mutect2, varscan2
